Somatic mutation profile of tumor specimen TCGA-29-1776-01A (aliquot TCGA-29-1776-01A-01W-0639-09) from TCGA case TCGA-29-1776, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,016 days).
Specimen TCGA-29-1776-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 217022ab-2cb3-4bbe-adf7-68a441c37153.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1776-10A (Blood Derived Normal), aliquot TCGA-29-1776-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d700232-b23a-49cf-9ac6-4f3faa3e3aa9

The open-access MAF lists 52 somatic variants for this specimen: 46 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Frame Shift Del 5, Silent 4, Splice Site 3, Nonsense Mutation 3, 5'UTR 2, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 48/58 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADA2 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831692; called by muse, mutect2, varscan2
- ANKS1B | c.2236C>A p.P746T | Missense Mutation (SNP) | VAF 99/116 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV61353455; called by muse, mutect2, varscan2
- APC | c.8422C>G p.P2808A | Missense Mutation (SNP) | VAF 113/137 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV57347666; called by muse, mutect2, varscan2
- APOB | c.12506A>T p.D4169V | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.386); catalogued as COSV51937449; called by muse, mutect2, varscan2
- AUTS2 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100715059; called by muse, mutect2
- BRCA1 | c.3562_3563del p.R1188Efs*3 | Frame Shift Del (DEL) | VAF 87/131 reads (66%) | catalogued as COSV58790945; called by mutect2, pindel, varscan2
- BRINP1 | c.2066C>G p.S689C | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV56301350; called by muse, mutect2, varscan2
- BRINP1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779421835, COSV56301357; called by muse, mutect2, varscan2
- C4orf50 | c.780C>G p.S260R (on ENST00000324058; = p.S1492R on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60688861; called by muse, mutect2, varscan2
- CFTR | c.182T>G p.L61R | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as CM057577, COSV99134183; called by muse, mutect2
- CSN1S1 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV55890820; called by muse, mutect2, varscan2
- DDX18 | c.360del p.D120Efs*51 | Frame Shift Del (DEL) | VAF 128/354 reads (36%) | catalogued as COSV54306861; called by mutect2, pindel, varscan2
- DIS3L2 | c.488A>C p.D163A | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99805526; called by muse, mutect2
- FAM207A | c.139T>C p.F47L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV52420616; called by muse, mutect2, varscan2
- GBA2 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV62305900; called by muse, mutect2, varscan2
- GRB14 | c.928-1G>T p.X310_splice | Splice Site (SNP) | VAF 51/100 reads (51%) | catalogued as COSV55738610; called by muse, mutect2, varscan2
- ITGB4 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.51); catalogued as COSV52326725; called by muse, mutect2, varscan2
- KIF13A | c.2985A>G p.I995M | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52452836; called by muse, mutect2, varscan2
- MED1 | c.3734C>A p.S1245* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100327409; called by muse, varscan2
- MON2 | c.3796T>G p.F1266V | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as COSV54808137; called by muse, mutect2, varscan2
- MYO3A | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.272); catalogued as COSV56332945; called by muse, mutect2, varscan2
- NAV2 | c.2399G>A p.R800K (on ENST00000396087 / NM_001244963.2; = p.R777K on NM_145117.5) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62324044; called by muse, mutect2, varscan2
- ORC2 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1489481306, COSV52239180; called by muse, mutect2, varscan2
- PAG1 | c.1127C>A p.A376E | Missense Mutation (SNP) | VAF 84/100 reads (84%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.555); catalogued as COSV55058185; called by muse, mutect2, varscan2
- PLPPR4 | c.1903C>G p.Q635E | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1262977814, COSV64566013; called by muse, mutect2, varscan2
- SDK1 | c.6128C>A p.T2043K | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.29); PolyPhen benign (0.147); catalogued as COSV67370935; called by muse, mutect2, varscan2
- SNTB1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 62/335 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV67326652; called by muse, mutect2, varscan2
- SQLE | c.1681A>G p.I561V | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1377198477, COSV56280998; called by muse, mutect2, varscan2
- STX16 | c.790C>T p.Q264* (on ENST00000371141 / NM_001001433.3; = p.Q243* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 41/127 reads (32%) | catalogued as COSV56606110; called by muse, mutect2, varscan2
- TCP1 | c.337C>A p.H113N | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58459069, COSV58459116; called by muse, mutect2, varscan2
- TMEM63B | c.1589C>G p.P530R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52479139, COSV52479422; called by muse, mutect2, varscan2
- UBE2K | c.400-1G>C p.X134_splice | Splice Site (SNP) | VAF 56/122 reads (46%) | catalogued as COSV54690570; called by muse, mutect2, varscan2
- USP32 | c.2953C>T p.R985* | Nonsense Mutation (SNP) | VAF 60/78 reads (77%) | catalogued as rs777749497, COSV56269692; called by muse, mutect2, varscan2
- WDR33 | c.154G>C p.V52L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV59249487; called by muse, mutect2, varscan2
- ZNF343 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 183/305 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.389); catalogued as COSV53854094; called by muse, mutect2, varscan2
- ZNF462 | c.5930A>G p.H1977R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52939564; called by muse, mutect2, varscan2
- AKAP6 | c.1058_1082del p.H353Lfs*45 | Frame Shift Del (DEL) | VAF 67/223 reads (30%) | called by mutect2, pindel, varscan2
- CLUL1 | c.987_994+7delinsGAC p.X329_splice | Splice Site (DEL) | VAF 20/80 reads (25%) | called by pindel, varscan2*
- FCGBP | c.6601G>T p.A2201S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- GLB1L3 | c.1030_1044del p.G344_G348del | In Frame Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- IL17RA | c.618C>A p.N206K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.087); called by muse, mutect2
- MEPE | c.1016del p.N339Tfs*73 | Frame Shift Del (DEL) | VAF 5/60 reads (8%) | called by mutect2, pindel
- NF1 | c.1770_1787del p.M590_E595del | In Frame Del (DEL) | VAF 31/54 reads (57%) | called by pindel, varscan2
- QSER1 | c.2759_2762del p.S920* (on ENST00000399302; = p.S1049* on NM_001076786.3) | Frame Shift Del (DEL) | VAF 67/172 reads (39%) | called by mutect2, pindel, varscan2
- TBC1D3L | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 34/36 reads (94%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CC2D2A | c.1053A>T p.L351= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV67503859; called by muse, mutect2, varscan2
- CKAP2L | c.828G>A p.R276= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as rs775471274, COSV100198471; called by muse, mutect2
- FOS | c.174C>A p.A58= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV100338419; called by muse, mutect2
- INTU | c.2052C>A p.S684= | Silent (SNP) | VAF 9/236 reads (4%) | catalogued as COSV100080472; called by muse, mutect2
- FCGR2A | c.-2G>A | 5'UTR (SNP) | VAF 41/88 reads (47%) | catalogued as COSV99614998; called by muse, mutect2, varscan2
- KANK4 | c.-2A>T | 5'UTR (SNP) | VAF 227/504 reads (45%) | catalogued as rs1025549770, COSV100587042, COSV62987812; called by muse, mutect2, varscan2
